Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8317, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8317-01A (Primary Tumor).

[page 1 of 7]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. DISTAL STOMACH, DUODENUM, HEAD OF PANCREAS, PANCREATODUODENECTOMY (WHIPPLE RESECTION):
- DUCTAL ADENOCARCINOMA, WELL DIFFERENTIATED.
- 3.1 cm in maximum dimension.
- Tumor invades ampulla of Vater and peripancreatic soft tissue.
- MARGIN STATUS: POSITIVE.
- Tumor extends to the superior peripancreatic soft tissue margin.
- Distal pancreatic, bile duct, and retroperitoneal margins are negative for tumor.
- FOUR OF THIRTEEN LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (4/13).
- PERINEURAL INVASION: NOT IDENTIFIED.
- SEE PATHOLOGIC TUMOR STAGING SUMMARY BELOW.
- B. UTERUS (74 GRAMS), LEFT FALLOPIAN TUBE AND OVARY, AND RIGHT ADNEXAL MASS, HYSTERECTOMY AND LEFT SALPINGO-OOPHORECTOMY:
- ENDOMETRIUM:
- Inactive endometrium.
- Negative for hyperplasia, neoplasia, and endometritis.
- MYOMETRIUM:
- Leiomyomata uteri (largest 2.2 cm in greatest dimension).
- Adenomyosis.
- SEROSA:
- Negative for adhesions and endometriosis.
- LEFT OVARY:
- Unremarkable ovarian tissue, negative for adhesions and endometriosis.
- RIGHT ADNEXAL LESION:
- Leiomyoma (4.5 cm in greatest dimension).
- Negative for cytologic atypia, increased mitotic activity and necrosis.

[page 2 of 7]
FINAL SURGICAL PATHOLOGY REPORT

C. APPENDIX, APPENDECTOMY:

- UNREMARKABLE VERMIFORM APPENDIX.
- FECALITH.

D. GALLBLADDER, CHOLECYSTECTOMY:

- ACUTE AND CHRONIC CHOLECYSTITIS.

E. RIGHT OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY:

- OVARIAN SEROSAL ADHESIONS.
- UNREMARKABLE PORTION OF FALLOPIAN TUBE.
- NEGATIVE FOR ENDOMETRIOSIS.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Ductal adenocarcinoma, well differentiated.

Primary tumor: pT3 (extends beyond the pancreas, but does not involve the celiac axis or superior mesenteric artery).

Regional lymph nodes: pN1 (four of thirteen lymph nodes, positive for metastasis).

Distant metastasis: Not applicable.

Pathologic stage: IIB.

Lymphovascular invasion: Present.

Margin status: R1 (tumor extends to superior peripancreatic soft tissue margin).

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook [REDACTED] and CAP protocol, [REDACTED]

[page 3 of 7]
Specimen:	Head of pancreas, duodenum, distal stomach, gallbladder.
Procedure:	Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy.
TUMOR FEATURES:	
Tumor site:	Pancreatic head.
Tumor size:	Greatest dimension: 3.1 cm.
Histologic type:	Ductal adenocarcinoma.
Histologic grade:	Well differentiated (G1).
Microscopic tumor extension:	Tumor invades ampullar of Vater and peripancreatic soft tissue.
MARGINS:	
Distance of invasive carcinoma from closest margin:	POSITIVE (R1). POSITIVE, at superior peripancreatic soft tissue margin.
Other margins:	Uninvolved by carcinoma.
Treatment effect:	Not applicable.
Lymphovascular invasion:	Present.
Perineural invasion:	Not identified.
LYMPH NODES:	
	Thirteen lymph nodes, four positive for metastatic carcinoma.
PATHOLOGIC TUMOR STAGING DESCRIPTORS:	
Primary tumor:	pT3 (tumor extends beyond the pancreas, without involvement of the celiac axis or the superior mesenteric artery).
Regional lymph nodes:	pN1 (4/13 lymph nodes positive for metastatic carcinoma).
Distant metastasis:	Not applicable.
Pathologic stage:	IIB.
Margin status:	R1 (tumor extends to superior peripancreatic soft tissue margin).

[page 4 of 7]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Whipple
- B. Left tube, ovary, uterus, and right adnexal mass
- C. Appendix
- D. Gallbladder
- E. Ovary and fallopian tube;right

Intraoperative Diagnosis:

A. Whipple procedure: Pancreatic mass, pelvic mass: FSA1) pancreatic margin negative. FSA2) Bile duct margin negative. [REDACTED] The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

B. FS: Left tube, ovary, uterus and right adnexal mass: Favor leiomyoma. [REDACTED]
The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]
[REDACTED]

Gross Description:

A. The specimen received at this time previously designated as #3, now designated as part A Whipple procedure. Initially received in a fresh state for frozen section analysis is a generous portion of tissue consistent with a Whipple procedure, consisting of a 10.3 cm distal portion of gastric tissue, 4.5 cm in diameter at the proximal margin of resection, a 17.5 x 3.2 cm fragment of small bowel, and the head pancreas measuring: 3.4 cm in length, 4.8 cm superior-inferior, and 4.3 cm anterior surface to posterior uncinete margin. The common bile duct extends 0.7 cm, and is 1.2 cm in diameter, with the dilated 0.6 cm lumen involved with a metallic mesh stent.

The surface of the pancreas is now differentially inked as follows: anterior-yellow, inferior-green, posterior uncinete-black, superior-blue, pancreatic notch/medial surface-red. The gastric and small bowel serosa demonstrates a glistening hyperemic appearance. The length of gastrointestinal tissue is now opened to reveal luminal contents of blood tinged mucinous fluid, that is cleared to reveal erythematous pink and tan gastric mucosa, with the small bowel circular plicae prominent, semi-congested distally, to light pink and tan. At 3.5 cm distal to the pylorus is a 0.2 cm unremarkable ductal orifice that is probe patent with the pancreatic duct through the distal margin. This ductal tract perpendicularly bypasses the common bile duct without involving the CBD lumen. At 1.1 cm distal to the pancreatic duct orifice, or 4.6 cm distal to the pylorus and 12.9 cm from the distal small bowel margin resection, a prominent ampulla, with a 1.0 cm lumen, demonstrates obvious communication with the common bile duct and involved with a metallic mesh stent. The stent is sectioned lengthwise and removed, revealing a waffled-granular, deep red

[page 5 of 7]
FINAL SURGICAL PATHOLOGY REPORT

congested mucosa. The small bowel periphery of the ampulla is raised, semi-congested and granular, over an area of 2.2 x 1.5 cm, with the immediate transition in the common bile duct suspiciously raised. The pancreatic margin and the common bile duct margin are now shaved and submitted for frozen section analysis, with residual frozen tissue submitted for permanent sections.

Sectioning through the pancreas, medial and posterior to the common bile duct tract, demonstrates diffusely dense, light gray cut surface, with mucin filled spaces up to 0.2 cm, grossly suspicious for malignant change. These changes grossly approach within 0.1 cm of the posterior margin of the uncinate and 0.1 cm of the superior-medial inked surfaces. This possible mass lesion is up to 3.1 x 1.8 cm. The remaining cut sections of the pancreas toward the anterior surface and distal margin of resection demonstrates tan, lobular, glandular parenchyma, grossly uninvolved with tumor, with exception of a 0.6 cm focus, suspicious for tumor involvement near the pancreatic groove periphery, and within 0.9 cm of the pancreatic distal margin of resection (A11). Examination of the peripancreatic fat reveals thirteen lymph node candidates ranging from 0.3 cm to 1.4 x 0.9 cm. Examination of the discrete portion of perigastric fat reveals two lymph node candidates, 0.3 and 0.4 cm each. Representative sections are submitted including entire submission of lymph node tissue candidacy.

Cassette summary: A1) distal pancreatic surgical margin, frozen section, A2) common bile duct surgical margin, frozen section, A3) pancreatic ampulla represented, A4-A5) common bile duct ampulla, possible tumor involvement, including pancreas, three pieces, A6) common bile duct length represented, posterior pancreas, possible tumor, A7) posterior surface of uncinate, possible tumor involvement, three pieces, A8) superior pancreas adjacent common bile duct, possible, two pieces, A9-A10) superior pancreas, pancreatic groove surface, possible tumor involvement, four pieces, A11) bulk of distal extension of pancreas, including inferior margin, possible tumor relationship, A12) additional representation of inferior pancreas, including mesenteric/pancreatic groove surface, A13) anterior pancreas represented, three pieces, A14) proximal gastric margin of resection represented, A15) distal small bowel margin of resection represented, A16) antrum of stomach, pylorus represented, two pieces, A17) representation of loop-distal duodenum, A18) six peripancreatic lymph nodes candidates, A19) four peripancreatic lymph node candidates, A20) fragmented peripancreatic lymph node candidate, A21) single peripancreatic lymph node candidate bisected, A22) single peripancreatic lymph node candidate bisected, grossly involved with tumor, A23) two gastric lymph node candidates, A24) perigastric fat, possible lymph node content. ■

B. Part B designated left tube, ovary, uterus, and right adnexa mass - stitch. Initially received in a fresh state for frozen section analysis is a supracervical hysterectomy specimen with attached left fallopian tube segment and ovary, and right adnexal mass. The right adnexal mass measures 4.5 x 3.7 x 3.5 cm and is encapsulated and partially glistening pink-red soft tissue. Sectioning reveals an encapsulated -well circumscribed rubbery, yellow-tan nodular cut surface, with a faint whorled appearance, grossly consistent with a leiomyoma. Two representative sections are submitted for frozen section analysis with residual frozen tissue submitted in B1 for permanent sections. The right fallopian tube segment and ovary is not appreciated, nor placed within the container, and the left adnexal tissue is now removed, to demonstrate a 74 gram uterine corpus including attached "right adnexal mass" measuring 5.7 cm superior to inferior, 4.5 cm cornu to cornu and 2.4 cm posterior-anterior. The uterine serosa is partially glistening light pink to congested deep purple-red. The uterine corpus is now bisected, revealing a triangular endometrium, 1.9 cm cornu to cornu and 3.0 cm in length, flattened light tan to focally congested deep red, and 0.1 cm in thickness. The dome of the fundus demonstrates an additional circumscribed whorled appearing nodular

[page 6 of 7]
FINAL SURGICAL PATHOLOGY REPORT

mass, 2.4 x 2.2 cm. The myometrium is rubbery semi-congested pink and tan and includes an additional 0.4 and 1.3 cm whorled appearing and somewhat degenerated yellow-gray nodules.

The left fallopian tube segment with fimbria is 4.7 x 0.4 cm congested deep red, with a delicate light tan lumen. The attached ovary is glistening bosselated pink-yellow, 2.4 x 1.7 x 1.3 cm. The ovary is partially cinched by a black suture, removed and the ovary is sectioned to demonstrate a soft to rubbery grossly atrophic pink and yellow-gray cut surface. Examination of the cinched area demonstrated increased indurated changes, including a 0.3 cm cyst, this area is entirely submitted for microscopic evaluation. The remaining cut sections of the ovary reveal discrete nodularity or grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted.

Section summary: B1) frozen section, "right adnexal mas", B2) cervical stump/distal margin of lower uterine segment, B3-B4) endomyometrium, including smallest nodularity, B5) large nodular mass and dome of fundus, second larger intramural mass represented, three pieces total, B6-B7) additional representation of large right adnexal mass, including surrounding margins, six pieces, B8) left fallopian tube and ovary represented. [REDACTED]

C. Part C designated appendix. Received is a container initially designated as part 1 appendix and part 2 gallbladder, includes a vermiform appendix, 7.0 cm in length, and 0.6 cm in diameter. The serosa is hyperemic pink and tan. Sectioning demonstrates a lumen dilated up to 0.4 cm containing loose green fecal matter. The apex demonstrates stenosis of lumen, thickened yellow-gray appearance. Representative sections are submitted to include entire submission of the apex, bisected, mid length, and proximal margin of resection represented (blue) in C1. [REDACTED]

D. Part D designated gallbladder. Received in formalin is a container formally designated as #1 appendix and #2 gallbladder, is a gallbladder, 7.0 x 2.6 x 1.5 cm. The serosa is glistening lightly fatty congested purple-red. The bile duct margin is received opened, demonstrating an obvious patent 0.3 cm lumen exuding hemorrhagic mucin. Examination of the attached fat near the cystic duct margin does not reveal lymph node content. The wall is 0.2 to 0.4 cm including serosal fat, and the lumen includes hemorrhagic mucin and blood clot, without calculi. The material is cleared to reveal velvety congested deep red mucosa with a few raised yellow flecks. No grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted for microscopic evaluation in D1. [REDACTED]

E. Part E designated as right tube and ovary. Received in formalin is a 6 gram portion of adnexal tissue, that includes a 4.0 x 0.3 cm fallopian tube segment with fimbria, and an attached 2.4 x 1.1 x 0.8 cm. The fallopian tube is hyperemic pink and tan, with a delicate light tan lumen. Sectioning through the ovary demonstrates a soft to rubbery semi-congested pink and yellow-gray, grossly atrophic parenchyma. No discrete nodularity or grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted, to include entire submission of the ovary, and representation of the fallopian tube in E1 and E2 [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

[page 7 of 7]
FINAL SURGICAL PATHOLOGY REPORT

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file 20d74166-5701-4e9d-98e6-32f4ba636ea5 (TCGA-HZ-8317.D0EA6C64-05F9-40BD-A69C-329334D20393.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).